Somatic mutation profile of tumor specimen TCGA-EL-A3CP-01A (aliquot TCGA-EL-A3CP-01A-11D-A19J-08) from TCGA case TCGA-EL-A3CP, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 50.1 years (18,298 days).
Specimen TCGA-EL-A3CP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dec85df7-f22e-4dc2-bee9-16216b917016.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3CP-10A (Blood Derived Normal), aliquot TCGA-EL-A3CP-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7723edf0-484d-4de1-9ec1-d4bb0f6e7e60

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CES1 | c.595C>A p.R199S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs563293177, COSV100828653, COSV62086839; called by muse, mutect2
- HK3 | c.1602G>A p.E534= | Splice Region (SNP) | VAF 14/57 reads (25%) | catalogued as COSV52841096; called by muse, mutect2, varscan2
- KIAA1109 | c.8243A>G p.E2748G | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52677124; called by muse, mutect2, varscan2
- ZNF407 | c.3473T>C p.F1158S | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV55256385; called by muse, mutect2, varscan2
- TDRD6 | c.819G>A p.S273= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as rs1432949626, COSV60175703; called by muse, mutect2
- WHRN | c.2331C>A p.G777= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as COSV54329543, COSV54331459; called by muse, mutect2, varscan2
